Gene-level copy-number profile of tumor specimen TCGA-63-5131-01A from TCGA case TCGA-63-5131, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-5131-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.bf694583-e371-4f45-bd75-e3fbf26f78c6.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-5131-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 405 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aa8a1d2d-95f1-429a-b6ac-eec54adaa8aa

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,260; copy number 2: 13,392; copy number 3: 11,248; copy number 4: 22,060; copy number 5: 8,102; copy number 6: 986; copy number 7: 1,620; copy number 8: 189; copy number 9: 573; copy number 10: 54; copy number 11: 435; copy number 12: 151; copy number 14: 52; copy number 18: 91.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-5131-01A-01D-1439-01): tumor purity 0.54, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:78,938,009–78,938,292, 1 gene: RN7SL751P.
- chr8:4,317,388–4,788,584, 4 genes: AC027251.1, AC010941.1, AC022068.1, PAICSP4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,356 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:60,057,601–65,271,253, 129 genes, copy number 9–18 (broad region; genes not listed).
- chr3:160,495,007–198,222,513, 665 genes, copy number 9–11 (within-gene range 4–11) (broad region; genes not listed).
- chr5:35,617,844–35,814,611, 1 gene, copy number 9 (within-gene range 8–9): SPEF2.
- chr5:35,678,484–36,588,661, 19 genes, copy number 9 (within-gene range 8–9): AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1.
- chr5:38,783,580–45,895,970, 107 genes, copy number 9–11 (broad region; genes not listed).
- chr8:36,887,456–42,555,195, 135 genes, copy number 12 (broad region; genes not listed).
- chr9:36,833,269–37,034,268, 1 gene, copy number 9 (within-gene range 4–9): PAX5.
- chr9:36,893,462–41,701,096, 142 genes, copy number 9 (broad region; genes not listed).
- chr16:29,973,868–31,074,240, 105 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr19:37,548,914–38,812,945, 52 genes, copy number 14 (within-gene range 2–14): ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4.

Autosomal genes at a single copy (total copy number 1): 546. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
